Gene-level copy-number profile of tumor specimen C3L-09811-01 from CPTAC case C3L-09811, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.0 years (26,290 days).
Specimen C3L-09811-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e015e9dd-82cd-465c-81c7-f9ea31c8f043.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09811-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,745 have no estimate.
https://portal.gdc.cancer.gov/files/ae19ed53-5588-4fa5-9517-eb058e57d960

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 3,071; copy number 2: 43,526; copy number 3: 9,764; copy number 4: 1,087; copy number 5: 1,397; copy number 7: 1; copy number 8: 17.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr21:44,107,373–44,131,181, 1 gene: PWP2.
- chr21:44,158,740–44,160,076, 1 gene: LINC01678.
- chr21:44,200,602–44,207,399, 1 gene: AP001057.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,415 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes, copy number 8: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr20:87,250–16,053,197, 288 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:15,552,157–64,327,972, 1,109 genes, copy number 5 (broad region; genes not listed).
- chr21:8,701,461–8,880,976, 6 genes, copy number 7–8: CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1.

Autosomal genes at a single copy (total copy number 1): 756. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
